Somatic mutation profile of tumor specimen TARGET-10-PARUKK-09A (aliquot TARGET-10-PARUKK-09A-01D) from TARGET case TARGET-10-PARUKK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,647 days).
Specimen TARGET-10-PARUKK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9e55556-7c01-4354-874d-af3da172d6e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUKK-10A (Blood Derived Normal), aliquot TARGET-10-PARUKK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ec06b91-8b80-4f2b-b0a9-dc117aed474a

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, RNA 2, Splice Region 2, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADH1A | c.261T>G p.G87= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as rs761698032, COSV52925187; called by muse, mutect2, varscan2
- LINC00587 | n.349C>T | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs576528912; called by muse, mutect2, varscan2
- PCDHA4 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63538719; called by muse, mutect2, varscan2
- CHD4 | c.3527A>C p.K1176T (on ENST00000357008 / NM_001363606.2; = p.K1189T on NM_001273.5) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CHD4 | c.3137_3138insTC p.K1047Pfs*17 (on ENST00000357008 / NM_001363606.2; = p.K1060Pfs*17 on NM_001273.5) | Frame Shift Ins (INS) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- GRIK3 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PAX5 | c.214T>C p.Y72H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFP36L2 | c.51+1_51+2insCCCCTTTTCG p.X17_splice | Splice Site (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- ZNF735 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- BAZ2B | c.2859C>A p.I953= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- CAVIN1 | c.798G>A p.T266= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs1298187185; called by muse, mutect2
- CNTLN | c.3384C>T p.H1128= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as rs529841744, COSV99263761; called by muse, mutect2, varscan2
- MBTPS1 | c.2286G>A p.L762= | Silent (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- ADAMTS7P1 | n.936G>T | RNA (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- GRM6 | c.2125-173C>A | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- HYDIN2 | n.5845G>A | RNA (SNP) | VAF 18/35 reads (51%) | catalogued as rs1349232924; called by muse, mutect2, varscan2
- ZNF300 | c.265+39G>A | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
